Surgical pathology report (de-identified scan), TCGA case TCGA-24-2267, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2267-01A (Primary Tumor).

[page 1 of 8]
CGA-24-2267

DIAGNOSTS-----

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS CARCINOMA,
- POORLY DIFFERENTIATED

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS
ADENOCARCINOMA, LYMPHATIC
PERMEATION

SOFT TISSUE, RIGHT PELVIC SIDE WALL, BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA,
METASTATIC

SOFT TISSUE, PELVIC PERITONEUM, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

SOFT TISSUE, ANTERIOR BLADDER, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

DIAPHRAGM, BIOPSY - NO HISTOPATHOLOGIC ABNORMALITIES

SOFT TISSUE, RIGHT GUTTER, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

SOFT TISSUE, LEFT GUTTER, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

SOFT TISSUE, POSTERIOR CUL-DE-SAC, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

SOFT TISSUE, LEFT PELVIC, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

SOFT TISSUE, RIGHT PELVIC, BIOPSY - NO HISTOPATHOLOGIC
ABNORMALITIES

OMENTUM, EXCISION - NO HISTOPATHOLOGIC ABNORMALITIES

APPENDIX, EXCISION - NO HISTOPATHOLOGIC ABNORMALITIES

LYMPH NODES, RIGHT PELVIC, EXCISION - NO HISTOPATHOLOGIC

[page 2 of 8]
Name: I

DIAGNOSIS (continued)

ABNORMALITIES (4/4)

LYMPH NODES, RIGHT OBTURATOR, EXCISION - NO HISTOPATHOLOGIC
ABNORMALITIES (6/6)

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION - NO HISTOPATHOLOGIC
ABNORMALITIES (6/6)

LYMPH NODES, LEFT OBTURATOR, EXCISION - NO HISTOPATHOLOGIC
ABNORMALITIES (5/5)

LYMPH NODES, PERIAORTIC, EXCISION - NO HISTOPATHOLOGIC
ABNORMALITIES (2/2)

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY - NO HISTOPATHOLOGIC
ABNORMALITIES

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY - INACTIVE

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY - LEIOMYOMAS

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY - NO HISTOPATHOLOGIC
ABNORMALITIES

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC
ABNORMALITIES

SPECIMEN(S) SUBMITTED

- Part 1: FS RIGHT ADRENAL MASS, EXCISION
- Part 2: X RIGHT ADRENAL MASS, EXCISION
- Part 3: LEFT TUBE OVARY
- Part 4: UTERUS, CERVIX
- Part 5: LEFT PELVIC PERITONEUM BIOPSY
- Part 6: ANTERIOR BLADDER BIOPSY
- Part 7: PELVIC SIDEWALL NODAL
- Part 8: RIGHT PELVIC LYMPH NODE
- Part 9: RIGHT OBTURATOR LYMPH NODE
- Part 10: LEFT EXTERNAL ILIAC LYMPH NODE

[page 3 of 8]
SPECIMEN(S) SUBMITTED

- Part 11: LEFT OBTURATOR LYMPH NODE
- Part 12: PARA AORTIC LYMPH NODE
- Part 13: OMENTUM BIOPSY
- Part 14: DIAPHRAGM BIOPSY
- Part 15: APPENDIX
- Part 16: LEFT GUTTER BIOPSY
- Part 17: RIGHT GUTTER BIOPSY
- Part 18: POSTERIOR CULDESAC BIOPSY
- Part 19: LEFT PELVIC BIOPSY
- Part 20: RIGHT PELVIC BIOPSY

HISTORY

The patient is [REDACTED] with a history of a complex right adnexal mass. Clinical diagnosis: Ovarian carcinoma. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy, appendectomy, and lymph node dissection. An intraoperative non-microscopic consultation was obtained and interpreted as: "Ovary, right, excision - A 450 gm ovary that measures 14.5 x 12 x 5.5 cm. The surface is nodular but smooth. The cut section shows yellowish tan tumor with mucoid and necrotic areas. A representative random section is submitted [REDACTED] Normal ovary or fallopian tube is not identified," by [REDACTED]

FROZEN

FS1: Right adnexal mass, excision - "Adenocarcinoma; cannot rule out metastasis" by [REDACTED]

GROSS

The specimens are received in twenty containers of formalin, each labeled with the patient's name. The first container is labeled [REDACTED] and contains two yellow, glistening core pieces of tissue, each measuring 1.5 x 1.5 x 0.1 cm. [REDACTED]

The second container is labeled "right adnexa, X1" and contains an already sectioned nodular mass of tissue, weighing 400 gm and measuring 13 x 11 x 5 cm in greatest dimension. The external surface is remarkable for a shiny, purple-white, fibrous capsule. It covers a nodular, firm, pale yellow tumor mass with focal areas of white, friable necrosis. Immediately beneath the capsule are

[page 4 of 8]
Name:

GROSS (continued)

occasional, unilocular cystic spaces filled with thin, clear fluid. These range in size from 0.5 to 2 cm in greatest dimension. Some of these contain coagulated blood-tinged fluid. A remnant of fimbriated fallopian tube, measuring 4 cm in length by 0.4 cm in diameter is attached via mesovarium to the main body of the mass. The fallopian tube itself is grossly unremarkable. Residual ovary is not identified. Further sectioning reveals an area within the mass that is multicystic with cysts being separated by shiny, glistening tan stroma. Labeled X1A and X1B, solid areas of tumor; X1C and X1D, multicystic areas of tumor; X1E, area of tumor with necrosis; X1F, fallopian tube. [REDACTED]

The third container is labeled "uterus and cervix" and contains a simple hysterectomy specimen, weighing 145 gm and measuring 10 x 8 x 3.5 cm in greatest dimension. The serosal surfaces are smooth, shiny, and tan. The endometrial cavity is distorted by numerous leiomyomata. It measures 1.7 cm in width by 3.4 cm in length. It is lined by smooth, tan, glistening endometrium, measuring 0.1 cm in depth. The average myometrial thickness is 2 cm, and the myometrium is notable for multiple solid white-tan, whorled, leiomyomata which exhibit no areas of hemorrhage, necrosis, or cystic degeneration. These range in size from 0.9 to 3 cm in greatest dimension. The endocervical canal measures 2.9 cm in length and is lined by unremarkable, shiny, yellow, furrowed endocervical mucosa. The cervical os measures 1.4 cm, and the ectocervix is lined by smooth, shiny, white epithelium with punctate areas of hemorrhage. Labeled 2. Jar 3. EM1 and EM2, anterior and posterior endomyometrium; C1 and C2, anterior and posterior cervix; [REDACTED]

The fourth container is labeled "left salpingo-oophorectomy" and contains an already sectioned adnexal structure, measuring 7 x 5.4 x 3 cm in greatest dimension. A multinodular tumor mass, measuring 5 x 5.5 x 3 cm arises from a remnant of fibrous nodular ovary, measuring 2.5 x 1.5 x 0.5 cm. The tumor is encapsulated by smooth, shiny gray capsule and does not appear on surfaces of the adnexal structures. The cut section reveals firm, solid, tan-yellow, glistening areas and multicystic areas. These latter areas are subcapsular. The tumor appears completely confined by capsule, and no tubal or broad ligament metastases are appreciated. The cysts are variably unilocular and multilocular and range in size from 0.1 to 1.5 cm in greatest dimension. They are variably empty or contain clear straw-colored fluid. The fallopian tube is fimbriated and measures 3.5 cm in length by 0.7 cm in diameter. It is unremarkable. Labeled Lot 1-Lot 5, tumor/ovary; Lot 6, fallopian tube. [REDACTED]

[page 5 of 8]
Name:

GROSS (continued)

The fifth container is labeled "left pelvic peritoneum biopsy" and contains an irregular pink-tan fragment of tissue, measuring 1.3 x 0.5 x 0.2 cm. [REDACTED]

The sixth container is labeled "anterior bladder biopsy" and contains a knarled irregular fragment of tan tissue, measuring 1 x 0.6 x 0.3 cm. Wrapped. [REDACTED]

The seventh container is labeled "right pelvic sidewall nodal" and contains six irregular and knarled pieces of tan-brown tissue, ranging in size from 0.5 x 0.5 x 0.5 cm to 1.1 x 0.8 x 0.6 cm. [REDACTED]

The eighth container is labeled "right pelvic lymph nodes" and contains an irregular piece of fibrofatty tissue, measuring 5 x 2 x 0.8 cm in greatest dimension. Four lymph nodes, ranging in size from 0.5 to 2.5 cm in greatest dimension are found and submitted. [REDACTED]

The ninth container is labeled "right obturator lymph nodes" and contains a mass of fibrofatty tissue, measuring 4.5 x 2.5 cm in greatest dimension. Multiple lymph nodes, ranging in size from 1 to 3 cm in greatest dimension. [REDACTED]

The tenth container is labeled "left external iliac lymph nodes" and contains an irregular mass of fibroadipose tissue, measuring 4.5 x 4.5 x 2 cm in greatest dimension. Seven lymph nodes, ranging in size from 1.5 to 2.8 cm in greatest dimension are found. Labeled F1 through F3. Jar 1.

~~The eleventh container is labeled "left obturator" and contains multiple lymph nodes, ranging in greatest dimension from 1.1 to 2.9 cm are found and submitted. [REDACTED]~~

The 12th container is additionally labeled "paraaortic" and contains a mass of fibroadipose tissue. Two lymph nodes, ranging in size from 0.9 to 2.2 cm are found and submitted. Labeled H. [REDACTED]

The thirteenth container is labeled "omentum" and contains a well-vascularized fibrofatty sheet of tissue, measuring 35 x 15 x 0.5 cm in greatest dimension. No areas are suspicious for metastatic tumor. [REDACTED]

The fourteenth container is labeled "diaphragm biopsy" and

[page 6 of 8]
[REDACTED]

Surg. Path. No.:

Name:

GROSS (continued)

contains one white fragment of tissue, measuring 0.2 x 0.2 x 0.2 cm in greatest dimension. [REDACTED]

The fifteenth container is labeled "appendix" and contains an appendix, measuring 6 cm in length by 0.5 cm in diameter. A small amount of periappendiceal fat is attached to the specimen. The serosal surface is smooth, shiny, and tan. The sectioned appendix is unremarkable. Labeled K, cross sections of upper and middle appendix, longitudinal section of lower appendix. [REDACTED]

The sixteenth container is labeled "right gutter" and contains a single fragment of white tissue, measuring 0.2 x 0.2 x 0.1 cm. [REDACTED]

The seventeenth container is labeled "left gutter biopsy" and contains two yellow and white fragments of tissue, each measuring 0.2 x 0.2 x 0.1 cm. Wrapped. [REDACTED]

The eighteenth container is labeled "posterior cul de sac biopsy" and contains a fragment of tissue, measuring 0.2 x 0.1 x 0.1 cm. [REDACTED]

The nineteenth container is labeled "left pelvic" and contains a fragment of white-tan tissue, measuring 0.2 x 0.1 x 0.1 cm. [REDACTED]

The twentieth container is labeled "right pelvic" and contains a curved tan fragment of tissue, measuring 0.5 x 0.1 x 0.1 cm. [REDACTED]

COMMENT

There is a poorly differentiated papillary serous carcinoma involving the right and left ovaries. Small foci of lymphatic invasion are identified in the lamina propria of the right fallopian tube, and there is metastatic papillary serous adenocarcinoma in the biopsy from the right pelvic side wall. There is no tumor elsewhere in the specimen including biopsies from the pelvic peritoneum, anterior bladder, diaphragm, right gutter, left gutter, posterior cul-de-sac, left pelvic, and right pelvic. Sections of the omentum and appendix show no significant histopathologic abnormalities. The lymph nodes, (4 right pelvic, 6 right obturator, 6 left external iliac, 5 left obturator, and 2 paraortic) are free of tumor. The endometrium is inactive. Leiomyomas are identified in the myometrium. There are no

[page 7 of 8]
[REDACTED]

Name:

Surg. Path. No.:

COMMENT (continued)

significant histopathologic abnormalities in the cervix or left fallopian tube. [REDACTED]

{End of Report}

[REDACTED]

Source: NCI Genomic Data Commons file 712667c0-01d7-4a63-80cf-4a63cd29248f (TCGA-24-2267.24844312-F32C-4366-945E-96D9A923F82A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).